Somatic mutation profile of tumor specimen TCGA-37-3789-01A (aliquot TCGA-37-3789-01A-01D-0983-08) from TCGA case TCGA-37-3789, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.1 years (23,782 days).
Specimen TCGA-37-3789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79782c2e-6618-4548-a654-d2106fdd7ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-3789-10A (Blood Derived Normal), aliquot TCGA-37-3789-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fa5f29b-6c7c-4b30-b8c3-e53ffb9387ad

The open-access MAF lists 308 somatic variants for this specimen: 239 protein-altering or splice-affecting, 60 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 60, Nonsense Mutation 23, Frame Shift Del 7, Splice Site 6, RNA 4, Splice Region 2, Frame Shift Ins 2, Intron 2, 3'Flank 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB4 | c.2484+1G>A p.X828_splice | Splice Site (SNP) | VAF 26/52 reads (50%) | catalogued as rs927772349, COSV62269495; ClinVar: pathogenic; called by mutect2, varscan2
- NDST1 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs606231456, CM119165, COSV55787571; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 61/145 reads (42%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs771025283, COSV52629476; called by muse, mutect2, varscan2
- AARS2 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1218013224, COSV55116336; called by mutect2, varscan2
- ACTN2 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs570051117, COSV63976710; called by muse, mutect2, varscan2
- ADAMTS8 | c.1096G>C p.G366R | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57295062; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.52-2A>G p.X18_splice | Splice Site (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100416818; called by muse, mutect2, varscan2
- AFF1 | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV57121805; called by muse, mutect2, varscan2
- AGAP6 | c.476G>C p.R159T (on ENST00000374056 / NM_001365867.1; = p.R182T on NM_001077665.2) | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.227); catalogued as COSV65018302; called by muse, mutect2, varscan2
- ALMS1 | c.8444C>G p.S2815* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as BM1674690, COSV52515106; called by muse, mutect2, varscan2
- ALPK2 | c.4895T>C p.I1632T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV64493873; called by muse, mutect2, varscan2
- ALPK3 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51936022; called by muse, mutect2, varscan2
- ANO4 | c.1753G>C p.E585Q (on ENST00000392977 / NM_001286615.2; = p.E550Q on NM_178826.4) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.41); catalogued as COSV54603881; called by muse, mutect2, varscan2
- APPBP2 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV50027884; called by mutect2, varscan2
- AQP11 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1184154429, COSV57992818; called by mutect2, varscan2
- ARHGEF11 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1306319821, COSV63814223; called by muse, mutect2, varscan2
- ASB18 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV68960882; called by muse, mutect2, varscan2
- ATG2A | c.5203G>A p.D1735N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65967574; called by muse, mutect2, varscan2
- ATXN3 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV61496387; called by mutect2, varscan2
- BAG4 | c.995C>A p.S332* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV54861203; called by muse, mutect2, varscan2
- BIRC3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs748637898, COSV54818367; called by mutect2, varscan2
- BIRC3 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV54818377; called by muse, mutect2, varscan2
- BIRC6 | c.10430C>T p.P3477L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV70202602, COSV70203385; called by muse, mutect2, varscan2
- BIRC6 | c.10861G>C p.E3621Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV70197921, COSV70202617; called by muse, mutect2, varscan2
- BRD4 | c.3708G>T p.E1236D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV54589881; called by muse, mutect2, varscan2
- BTG1 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55459101, COSV55459614; called by muse, mutect2, varscan2
- C11orf80 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs766113733, COSV60930143; called by mutect2, varscan2
- C5orf34 | c.1780T>C p.S594P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV60931127; called by muse, mutect2, varscan2
- C5orf34 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs970341048, COSV60931137; called by muse, mutect2, varscan2
- CA10 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1368093615, COSV53359246; called by muse, mutect2, varscan2
- CAB39L | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV61715783; called by muse, mutect2, varscan2
- CCDC180 | c.3828C>G p.F1276L | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63832287; called by muse, mutect2, varscan2
- CCDC88A | c.4642T>A p.F1548I (on ENST00000436346 / NM_001365480.1; = p.F1520I on NM_018084.5) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV55065516; called by muse, mutect2, varscan2
- CCT8L2 | c.589A>G p.S197G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV63463123; called by muse, mutect2, varscan2
- CD101 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56715694; called by muse, mutect2, varscan2
- CDH18 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV56912409, COSV56939656; called by mutect2, varscan2
- CDH8 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100181663, COSV54881609; called by mutect2, varscan2
- CEP290 | c.4322C>G p.S1441* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV58352400, COSV58353679; called by muse, mutect2, varscan2
- CFAP36 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1196311266, COSV55406808; called by muse, mutect2, varscan2
- CFAP65 | c.3754G>C p.E1252Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as COSV58563528, COSV58567614; called by muse, mutect2
- CH25H | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs769631394, COSV64092426; called by muse, mutect2, varscan2
- CHTF18 | c.2737G>C p.E913Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV50210724; called by muse, mutect2, varscan2
- CLK2 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62877695; called by muse, mutect2, varscan2
- CLRN2 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV55551123; called by muse, mutect2
- CMAS | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57557020; called by mutect2, varscan2
- CNKSR3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755857610, COSV70480968, COSV70481254; called by mutect2, varscan2
- COL11A2 | c.3203T>A p.V1068E (on ENST00000341947 / NM_080680.3; = p.V961E on NM_080679.2) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59499343; called by muse, mutect2, varscan2
- COL1A1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.03); catalogued as rs1466255265, COSV56807223; called by muse, mutect2
- CSMD3 | c.9095C>G p.S3032* (on ENST00000297405 / NM_001363185.1; = p.S2863* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV52240971; called by muse, mutect2, varscan2
- CSMD3 | c.7246G>T p.G2416C (on ENST00000297405 / NM_001363185.1; = p.G2312C on NM_052900.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52240990; called by mutect2, varscan2
- CX3CR1 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64194453; called by muse, mutect2, varscan2
- DCDC2 | c.1057G>T p.G353* | Nonsense Mutation (SNP) | VAF 34/62 reads (55%) | catalogued as COSV65829318; called by muse, mutect2, varscan2
- DIP2C | c.3872G>A p.R1291Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778650086, COSV55167447, COSV99792482; called by muse, mutect2, varscan2
- DNAH5 | c.9911C>T p.S3304L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs139821753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54238309; called by muse, mutect2, varscan2
- DNMT3A | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs774100557, COSV53043935, COSV53053053; called by mutect2, varscan2
- DYNC1LI1 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV56128341; called by muse, mutect2, varscan2
- EIF3L | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV66045741; called by muse, mutect2, varscan2
- ENPP7 | c.271C>G p.H91D | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60387120; called by muse, mutect2, varscan2
- ESF1 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV52522575; called by muse, mutect2, varscan2
- ESRRG | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63169694; called by mutect2, varscan2
- ESYT3 | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV56680989; called by muse, varscan2
- EVC | c.615G>A p.E205= | Splice Region (SNP) | VAF 8/21 reads (38%) | catalogued as COSV53835025; called by muse, mutect2, varscan2
- EZH2 | c.1652C>G p.S551* (on ENST00000460911 / NM_001203247.2; = p.S556* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV57457105; called by muse, mutect2, varscan2
- FAM227B | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54814745; called by muse, mutect2, varscan2
- FANCM | c.4828G>A p.E1610K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV57503417; called by mutect2, varscan2
- FCRL5 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as COSV62517179; called by muse, varscan2
- FGGY | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV58038450; called by muse, mutect2, varscan2
- FLCN | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as rs886052661, COSV53261186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT1 | c.3211A>T p.I1071F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56734042; called by muse, mutect2, varscan2
- FMN2 | c.1803G>T p.W601C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60439964; called by mutect2, varscan2
- FNDC7 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV54755861; called by mutect2, varscan2
- G3BP2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV62976874; called by muse, mutect2
- GADL1 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56981963; called by muse, mutect2, varscan2
- GPRC5C | c.1363G>T p.A455S (on ENST00000652232; = p.A410S on NM_018653.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV61237859; called by muse, varscan2
- GRIN2A | c.4317C>A p.Y1439* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV58044559; called by muse, mutect2, varscan2
- GRM5 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59596727, COSV59614892; called by mutect2, varscan2
- H3C10 | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV60798292; called by mutect2, varscan2
- HERC1 | c.11777G>T p.W3926L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV71248881; called by muse, mutect2, varscan2
- HFM1 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV54031945, COSV99645833; called by mutect2, varscan2
- HINT2 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV52414738; called by muse, mutect2, varscan2
- HIVEP1 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as COSV65103327; called by muse, mutect2, varscan2
- HIVEP2 | c.6290G>C p.R2097T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV50024935, COSV99173376; called by muse, mutect2, varscan2
- HLA-DRB1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); catalogued as COSV63517880; called by mutect2, varscan2
- HLA-DRB5 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV66615232; called by mutect2, varscan2
- HLF | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56830789; called by muse, mutect2
- HRC | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53257495; called by muse, mutect2, varscan2
- HRNR | c.5239C>T p.R1747C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs1483753921; called by mutect2, varscan2
- HTR1B | c.735C>A p.N245K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV64051675; called by muse, mutect2, varscan2
- ILDR2 | c.555A>T p.P185= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as COSV54833040; called by muse, mutect2, varscan2
- INHBC | c.829A>T p.I277L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59005665; called by muse, mutect2, varscan2
- INPP5B | c.2265C>G p.D755E (on ENST00000373023; = p.D675E on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV65961667; called by muse, mutect2, varscan2
- IRS4 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 104/181 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as COSV64534836; called by muse, mutect2, varscan2
- ITGA10 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65198184; called by muse, mutect2, varscan2
- ITIH5 | c.402-1G>C p.X134_splice | Splice Site (SNP) | VAF 25/51 reads (49%) | catalogued as rs747628441, COSV56909053; called by muse, mutect2, varscan2
- KCNB2 | c.783C>G p.F261L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73051414, COSV73051535; called by muse, mutect2
- KCNJ3 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54539738; called by muse, varscan2
- KIF20A | c.1502C>G p.S501* | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as COSV67510207; called by muse, mutect2, varscan2
- KMO | c.90G>C p.R30S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs946990907, COSV100844827, COSV63809435; called by muse, mutect2, varscan2
- KMT2D | c.4223G>T p.C1408F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56421577, COSV56461887; called by muse, mutect2
- LCP1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as COSV59941959; called by muse, mutect2, varscan2
- LIN37 | c.642G>C p.W214C | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50000933; called by muse, mutect2, varscan2
- LIPI | c.865T>A p.C289S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60707585; called by muse, mutect2, varscan2
- MAP10 | c.1564C>G p.Q522E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.954); catalogued as COSV69364197; called by muse, mutect2, varscan2
- MATN1 | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65651005; called by mutect2, varscan2
- MCHR2 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV56005485; called by muse, mutect2, varscan2
- MFSD9 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV51494761; called by muse, mutect2
- MMD2 | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV68661153; called by muse, mutect2, varscan2
- MON2 | c.3590T>C p.V1197A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV54810316; called by muse, mutect2, varscan2
- MOXD1 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60943066, COSV60946016; called by muse, mutect2
- MS4A2 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.424); catalogued as COSV54013125; called by muse, varscan2
- MSL2 | c.1631G>T p.S544I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV53867298; called by muse, mutect2, varscan2
- MTHFD2L | c.220T>A p.W74R (on ENST00000395759 / NM_001144978.2; = p.W16R on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57468807; called by muse, mutect2, varscan2
- MTHFD2L | c.221G>T p.W74L (on ENST00000395759 / NM_001144978.2; = p.W16L on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.47); PolyPhen benign (0.364); catalogued as COSV57468814; called by muse, mutect2, varscan2
- MTMR11 | c.853G>C p.D285H (on ENST00000439741 / NM_001145862.2; = p.D213H on NM_181873.3) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV63807279; called by muse, mutect2, varscan2
- MTMR6 | c.695G>C p.R232P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV67808920; called by muse, mutect2, varscan2
- MTR | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV63968767; called by muse, mutect2, varscan2
- MUC17 | c.8957G>A p.R2986K | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV60293172; called by muse, mutect2, varscan2
- MUC5AC | c.14030G>C p.R4677P | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); catalogued as COSV100611475; called by muse, mutect2, varscan2
- NEK8 | c.621C>G p.N207K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52043932, COSV52046739; called by muse, varscan2
- NLRP10 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV60781186, COSV60782193; called by muse, mutect2, varscan2
- NLRP4 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56715158, COSV56718184; called by mutect2, varscan2
- NLRP4 | c.2699T>G p.L900W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56718204; called by muse, mutect2, varscan2
- NR1I2 | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV61978960; called by muse, mutect2, varscan2
- NRAP | c.2573T>A p.L858Q (on ENST00000359988 / NM_001322945.2; = p.L823Q on NM_006175.4) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.925); catalogued as COSV63492305; called by muse, mutect2, varscan2
- NRG1 | c.1062-2A>T p.X354_splice (on ENST00000405005 / NM_013964.5; = p.X359_splice on NM_013956.5) | Splice Site (SNP) | VAF 13/40 reads (33%) | catalogued as COSV55167104; called by muse, mutect2, varscan2
- NRP1 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55171362; called by muse, varscan2
- NYAP2 | c.835T>G p.L279V | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV56010547; called by muse, mutect2, varscan2
- OR2T33 | c.467T>G p.L156R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs372903370; called by muse, mutect2, varscan2
- OR51G1 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1251974432, COSV58969809; called by muse, mutect2, varscan2
- OR5AR1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs758374441, COSV57254483; called by mutect2, varscan2
- OR5M1 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV101591561, COSV73202033, COSV73202262; called by mutect2, varscan2
- OR5R1 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56572941; called by muse, mutect2, varscan2
- PAK3 | c.1352G>C p.R451P (on ENST00000262836 / NM_001324328.2; = p.R436P on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53277405, COSV99458618; called by muse, mutect2, varscan2
- PARP8 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55863005; called by mutect2, varscan2
- PCDH11X | c.2728G>T p.D910Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53484616; called by muse, mutect2, varscan2
- PCDHB13 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV53393802, COSV53398699; called by mutect2, varscan2
- PCDHB2 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV50593315; called by muse, mutect2, varscan2
- PCDHGA5 | c.2279C>G p.T760S | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV53984631; called by muse, mutect2, varscan2
- PCSK2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV52737497; called by muse, mutect2, varscan2
- PCSK6 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as rs1267762947, COSV59341117; called by muse, mutect2, varscan2
- PEX6 | c.2940C>A p.C980* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV55104134, COSV99769507; called by mutect2, varscan2
- PHF3 | c.2755G>T p.A919S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV50326152; called by muse, mutect2, varscan2
- PLXNA4 | c.4244A>G p.K1415R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV58142194; called by muse, mutect2, varscan2
- PLXNA4 | c.2990A>G p.H997R | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs1261798834, COSV58142220; called by muse, mutect2, varscan2
- PPP1R36 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV53902946; called by mutect2, varscan2
- PPP2R5C | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV58273807; called by mutect2, varscan2
- PPP3R2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201878659, COSV62456005; called by muse, mutect2, varscan2
- PRAMEF4 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs145911043; called by muse, varscan2
- PRICKLE1 | c.2417C>A p.P806H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.237); catalogued as COSV58208584; called by muse, mutect2, varscan2
- PRKAG3 | c.1460T>A p.L487H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52102795; called by mutect2, varscan2
- PRKD1 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs780325838, COSV59576750; called by mutect2, varscan2
- PRRC2B | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1480145227, COSV61939999; called by muse, varscan2
- PTPRB | c.4983G>T p.R1661S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV54241263, COSV54246636; called by mutect2, varscan2
- PTPRF | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs757666619, COSV63446672; called by muse, mutect2, varscan2
- PYHIN1 | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs1434732005, COSV63723162; called by muse, mutect2, varscan2
- RAE1 | c.1021-2A>G p.X341_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV64798472; called by muse, mutect2
- RDH5 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV57676739; called by muse, mutect2, varscan2
- RHAG | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57703666, COSV57705247; called by muse, mutect2, varscan2
- RNF214 | c.1893C>G p.I631M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV56117824, COSV56119900; called by muse, mutect2, varscan2
- RPGR | c.2428G>C p.E810Q (on ENST00000339363 / NM_001367249.1; = p.E605Q on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV58837259; called by muse, mutect2, varscan2
- RYR3 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV66799796; called by muse, mutect2, varscan2
- SASH1 | c.3733G>C p.E1245Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.342); catalogued as COSV66563282; called by muse, mutect2, varscan2
- SEC61G | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV61856118; called by muse, mutect2
- SEMG2 | c.1400C>A p.S467* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV65647698; called by muse, mutect2, varscan2
- SEPTIN14 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs1489801308, COSV66429119; called by muse, mutect2, varscan2
- SETX | c.2255C>T p.T752I | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56389366; called by muse, mutect2, varscan2
- SH3TC1 | c.1244-1G>A p.X415_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | catalogued as COSV55286802; called by muse, mutect2, varscan2
- SIPA1L2 | c.2111A>G p.N704S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53394375; called by muse, mutect2, varscan2
- SIX3 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV53226745, COSV53227833; called by muse, mutect2, varscan2
- SLC12A1 | c.1551A>T p.K517N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66797047; called by muse, mutect2, varscan2
- SLC6A15 | c.2071G>T p.G691C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.77); catalogued as COSV57026259; called by mutect2, varscan2
- SLCO2A1 | c.1177T>C p.S393P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV60487312; called by muse, mutect2, varscan2
- SLIT3 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as rs1394577013, COSV60602066; called by muse, mutect2, varscan2
- SMARCAD1 | c.2843A>T p.D948V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62775250; called by muse, mutect2, varscan2
- SNX1 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV56039015; called by muse, mutect2, varscan2
- SORBS1 | c.536C>G p.P179R (on ENST00000361941 / NM_001034954.2; = p.P147R on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV53361091; called by muse, mutect2, varscan2
- SOX1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58379669; called by mutect2, varscan2
- SP100 | c.2150G>T p.C717F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60847336; called by muse, mutect2, varscan2
- SPAG6 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57619871, COSV57621943; called by muse, mutect2, varscan2
- SPP1 | c.598G>A p.G200S (on ENST00000395080 / NM_001040058.2; = p.G186S on NM_000582.2) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV52952189; called by muse, mutect2, varscan2
- STXBP5L | c.874C>G p.H292D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56523103; called by muse, mutect2, varscan2
- SUCLA2 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66222496; called by muse, mutect2, varscan2
- SUN5 | c.570C>A p.H190Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62181730; called by muse, mutect2, varscan2
- TAS2R42 | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.377); catalogued as COSV62084769; called by muse, mutect2, varscan2
- TBC1D9 | c.2166G>C p.L722F | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101464405, COSV71307963; called by muse, mutect2, varscan2
- TESK2 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59154802; called by muse, mutect2, varscan2
- TEX101 | c.633T>A p.H211Q (on ENST00000598265 / NM_001130011.3; = p.H229Q on NM_031451.4) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs375174329, COSV53662439; called by muse, mutect2, varscan2
- TF | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.749); catalogued as COSV53918665, COSV53921878; called by muse, mutect2, varscan2
- TFB1M | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV51642422; called by muse, mutect2, varscan2
- TGIF2LX | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52214549; called by muse, mutect2, varscan2
- TJP3 | c.1302C>G p.F434L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53664043; called by muse, mutect2, varscan2
- TMC3 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.246); catalogued as rs200101447; called by muse, mutect2, varscan2
- TMC5 | c.1404C>G p.F468L (on ENST00000396229 / NM_001105248.1; = p.F222L on NM_024780.5) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV54906685, COSV54907341; called by muse, mutect2, varscan2
- TMPRSS5 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV55424861; called by muse, mutect2, varscan2
- TNC | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 84/146 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV60787191; called by muse, mutect2, varscan2
- TPR | c.6103C>G p.Q2035E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV66602965; called by muse, mutect2
- TRIM48 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70161448; called by mutect2, varscan2
- TRPS1 | c.769G>A p.D257N (on ENST00000220888 / NM_001330599.2; = p.D270N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1356080084, COSV55250780; called by muse, mutect2, varscan2
- UBR4 | c.15467C>T p.S5156L | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV64393977; called by muse, mutect2, varscan2
- UBR4 | c.4175A>T p.Q1392L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.838); catalogued as COSV64393992; called by muse, mutect2, varscan2
- UGT2B28 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs371664274, COSV59430439; called by mutect2, varscan2
- UGT8 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60419242; called by mutect2, varscan2
- USH2A | c.8431C>T p.P2811S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as COSV56398290; called by muse, mutect2, varscan2
- VSIG2 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.281); catalogued as COSV52518966; called by muse, mutect2, varscan2
- WDPCP | c.1402A>G p.R468G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55425553; called by muse, mutect2, varscan2
- WDR25 | c.657G>T p.E219D | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58938074; called by muse, mutect2, varscan2
- WDR93 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV51533731; called by muse, mutect2, varscan2
- WNK1 | c.6023A>G p.N2008S (on ENST00000315939 / NM_018979.4; = p.N1760S on NM_014823.3) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as COSV60038992; called by muse, mutect2, varscan2
- XRN1 | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV53814766; called by muse, mutect2, varscan2
- XYLT1 | c.1096T>G p.Y366D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54489995; called by muse, mutect2, varscan2
- ZBED4 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV53466735; called by muse, mutect2, varscan2
- ZBTB9 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV67702235; called by muse, mutect2, varscan2
- ZFHX3 | c.3616C>G p.L1206V | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV51726056; called by muse, mutect2, varscan2
- ZFP14 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as COSV54203486; called by muse, mutect2, varscan2
- ZNF23 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV61841304; called by mutect2, varscan2
- ZNF335 | c.2309C>G p.S770C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV59818792; called by muse, varscan2
- ZNF391 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.608); catalogued as rs777522196, COSV55122226; called by mutect2, varscan2
- ZNF420 | c.2018A>G p.Y673C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747580016, COSV58495067; called by muse, mutect2, varscan2
- ZNF425 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.914); catalogued as COSV100955571, COSV65201856; called by muse, varscan2
- ZNF43 | c.1946C>G p.P649R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1414975525, COSV61684757; called by muse, mutect2, varscan2
- ZNF45 | c.1454C>G p.S485* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54193910; called by muse, mutect2, varscan2
- ZNF559 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV57836392; called by muse, mutect2
- ZNF681 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68074862; called by mutect2, varscan2
- ZNF80 | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV57361764; called by muse, varscan2
- BAK1 | c.593_603del p.V198Afs*103 | Frame Shift Del (DEL) | VAF 22/37 reads (59%) | called by mutect2, pindel, varscan2
- CELF6 | c.484_485insT p.E162Vfs*9 | Frame Shift Ins (INS) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- CXCR4 | c.957dup p.V320Cfs*24 | Frame Shift Ins (INS) | VAF 114/432 reads (26%) | called by mutect2, pindel, varscan2
- GLIS3 | c.2183del p.G728Afs*103 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LRRC28 | c.1015del p.A339Qfs*28 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- SCN2A | c.4del p.A2? | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- SIK2 | c.1053_1069del p.G352* | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- SORCS1 | c.2740_2754del p.W914_V918del | In Frame Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZFYVE9 | c.467_483del p.N156Ifs*9 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel
- ZNF160 | c.2301del p.A769Pfs*4 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- ZNF26 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- ABCG8 | c.1149C>T p.T383= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1477642475, COSV55394792; called by muse, mutect2, varscan2
- ACVR1 | c.846T>C p.I282= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV55120518; called by muse, mutect2, varscan2
- ANKRD52 | c.1587C>T p.A529= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV57285713; called by muse, mutect2, varscan2
- CFHR4 | c.1170T>A p.I390= (on ENST00000367416 / NM_001201551.2; = p.I144= on NM_006684.5) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs755445759, COSV52232058; called by mutect2, varscan2
- CIT | c.5235C>T p.L1745= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as COSV55875092; called by muse, mutect2, varscan2
- COL12A1 | c.5052C>G p.L1684= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV59400762; called by muse, mutect2, varscan2
- DOCK3 | c.5235G>C p.L1745= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV56534052; called by muse, mutect2, varscan2
- DYNC1H1 | c.13368G>T p.V4456= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1364317730, COSV64139208; called by mutect2, varscan2
- ELAC2 | c.2166G>A p.L722= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV52396860; called by mutect2, varscan2
- ELAVL2 | c.669C>T p.N223= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs767990129, COSV56365662; called by mutect2, varscan2
- FCGR1A | c.606C>T p.L202= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV64985767; called by mutect2, varscan2
- GABRB1 | c.888C>A p.T296= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV54970363, COSV54990898; called by mutect2, varscan2
- GALR1 | c.432C>A p.S144= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55318088; called by mutect2, varscan2
- GPR132 | c.936G>A p.T312= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs901453790, COSV61678154, COSV61678257; called by muse, mutect2, varscan2
- GRIN2C | c.2577C>T p.F859= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV53115437; called by mutect2, varscan2
- HEATR1 | c.4572C>G p.L1524= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV63982082; called by muse, mutect2, varscan2
- HIVEP3 | c.4671G>A p.K1557= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs573083888, COSV56018758; called by muse, mutect2, varscan2
- HOXA11 | c.111C>A p.T37= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV50053856; called by mutect2, varscan2
- IQUB | c.1653A>G p.G551= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV61238061; called by muse, varscan2
- ITIH5 | c.2505C>A p.S835= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV53669775; called by muse, mutect2, varscan2
- ITPRIP | c.1284C>T p.L428= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV53392296; called by muse, mutect2, varscan2
- KCNV1 | c.948G>C p.L316= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV52086433, COSV52087348, COSV52088638; called by muse, mutect2, varscan2
- LPA | c.5949T>C p.T1983= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV60305329; called by muse, mutect2, varscan2
- MAP2 | c.2640A>G p.P880= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52298692; called by muse, mutect2, varscan2
- MYH3 | c.2889C>A p.A963= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV56867238; called by muse, mutect2, varscan2
- N4BP2 | c.3762A>G p.L1254= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV54704326; called by muse, mutect2, varscan2
- NHLRC3 | c.765C>T p.F255= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV65463163; called by muse, mutect2, varscan2
- NHSL2 | c.1947C>G p.L649= (on ENST00000510661; = p.L1015= on NM_001013627.2) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV65454101; called by muse, mutect2, varscan2
- NOD2 | c.2901C>G p.L967= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV56051582, COSV56052886, COSV56052914; called by muse, mutect2, varscan2
- NPAP1 | c.2574G>A p.G858= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV61504677; called by muse, mutect2, varscan2
- NPHS1 | c.2064C>G p.L688= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV62288916; called by muse, mutect2, varscan2
- OR11H12 | c.120C>A p.I40= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs1253905762, COSV73543477; called by mutect2, varscan2
- OR2T4 | c.547C>T p.L183= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV63543190; called by muse, mutect2, varscan2
- OR5D13 | c.537T>C p.F179= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV62334494; called by muse, mutect2, varscan2
- PACC1 | c.462C>T p.I154= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV54788685; called by mutect2, varscan2
- PDCD11 | c.867G>A p.Q289= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV63934521; called by mutect2, varscan2
- PHACTR3 | c.303C>A p.G101= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV63030952; called by muse, mutect2, varscan2
- PPP1R13L | c.2406G>T p.A802= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV62907875, COSV62909074; called by muse, varscan2
- RFPL2 | c.48C>A p.S16= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV50727001; called by mutect2, varscan2
- RUNX1 | c.363C>T p.T121= (on ENST00000344691 / NM_001001890.3; = p.T148= on NM_001754.5) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs773689002, COSV100278418, COSV55872606; ClinVar: likely benign; called by muse, mutect2, varscan2
- SALL3 | c.1977G>A p.S659= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV73305750; called by muse, mutect2, varscan2
- SHISA4 | c.252G>A p.K84= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs767642403, COSV62884691; called by muse, mutect2, varscan2
- SHMT1 | c.396G>T p.V132= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV57399620; called by muse, mutect2, varscan2
- SLC1A7 | c.1449G>T p.R483= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV57015177; called by mutect2, varscan2
- SLC35G1 | c.876G>T p.G292= (on ENST00000427197 / NM_001134658.3; = p.G291= on NM_153226.4) | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV65055536; called by muse, mutect2, varscan2
- SLC45A4 | c.1323G>C p.R441= (on ENST00000517878 / NM_001286646.2; = p.R390= on NM_001080431.2) | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV50147658; called by muse, mutect2, varscan2
- SLC6A2 | c.756C>G p.L252= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV54919584; called by muse, mutect2, varscan2
- SORBS1 | c.921C>G p.V307= (on ENST00000361941 / NM_001034954.2; = p.V143= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV53361071; called by muse, mutect2, varscan2
- SUPT5H | c.546C>G p.V182= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV63240870; called by muse, mutect2, varscan2
- TBRG1 | c.1155G>A p.L385= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV99422779; called by muse, mutect2, varscan2
- TJP3 | c.1488C>T p.F496= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV53664053; called by mutect2, varscan2
- TPR | c.1917A>G p.A639= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV66602977; called by muse, mutect2, varscan2
- TRIML1 | c.897C>G p.L299= | Silent (SNP) | VAF 60/164 reads (37%) | catalogued as COSV60193494, COSV60195535; called by muse, mutect2, varscan2
- TUBA4A | c.1344A>G p.E448= | Silent (SNP) | VAF 67/243 reads (28%) | catalogued as COSV50279283; called by muse, mutect2, varscan2
- TYRP1 | c.585A>C p.S195= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV66358137; called by muse, mutect2, varscan2
- WWC2 | c.3390A>G p.E1130= | Silent (SNP) | VAF 71/155 reads (46%) | catalogued as COSV67860049; called by muse, mutect2, varscan2
- YTHDC2 | c.918G>A p.T306= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs771721041, COSV50739965; called by mutect2, varscan2
- ZNF10 | c.1443G>A p.R481= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV50213288; called by muse, mutect2, varscan2
- ZNF229 | c.699C>T p.F233= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs767719834, COSV52160860; called by muse, mutect2, varscan2
- ZNF839 | c.1155G>A p.L385= (on ENST00000558850 / NM_001267827.1; = p.L501= on NM_018335.5) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV51758340; called by muse, mutect2, varscan2
- AGAP7P | n.1174G>T | RNA (SNP) | VAF 84/214 reads (39%) | called by muse, mutect2, varscan2
- DIRC1 | n.451C>T | RNA (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57368584; called by mutect2, varscan2
- ECM2 | chr9:92494108 G>A | 3'Flank (SNP) | VAF 29/100 reads (29%) | catalogued as COSV60740333, COSV60741945; called by muse, mutect2, varscan2
- KIF16B | c.3498+3326C>G | Intron (SNP) | VAF 38/129 reads (29%) | catalogued as COSV100734796; called by muse, mutect2, varscan2
- KIR3DX1 | n.167C>T | RNA (SNP) | VAF 7/63 reads (11%) | catalogued as rs372931579; called by mutect2, varscan2
- MIR495 | n.34C>T | RNA (SNP) | VAF 8/56 reads (14%) | catalogued as rs1387305475; called by mutect2, varscan2
- RN7SL484P | chr15:99791730 G>A | 3'Flank (SNP) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- TRIM36 | c.64-7407A>T | Intron (SNP) | VAF 32/100 reads (32%) | catalogued as COSV99142571; called by muse, mutect2, varscan2
- XIRP2 | c.*438T>A | 3'UTR (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99746251; called by muse, mutect2, varscan2
